Surgical pathology report (de-identified scan), TCGA case TCGA-IQ-A6SH, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Miami, specimen TCGA-IQ-A6SH-01A (Primary Tumor).

[page 1 of 5]
Surgical Pathology Report

Name:	XX	Case #:	xx
DOB:		Collected:	
Gender:	M	Received:	
MRN:	X	Reported:	
Location:	X	Copy To:	
Physician:	X		

Pathologic Interpretation:

A. LEFT VENTRAL TONGUE MUCOSAL MARGIN :

No malignancy seen.

B. LEFT ANTERIOR FLOOR OF MOUTH:

No malignancy seen.

C. LEFT LINGUAL NERVE:

No malignancy seen.

D. LEFT POSTERIOR FLOOR OF MOUTH MUCOSAL MARGIN:

No malignancy seen.

E. LEFT DORSAL TONGUE MUCOSAL MARGIN:

No malignancy seen.

F. DEEP MARGIN MID-TONGUE:

No malignancy seen.

G. DEEP MARGIN POSTERIOR TONGUE:

No malignancy seen.

H. DEEP MARGIN ANTERIOR TONGUE:

No malignancy seen.

I. LEFT HEMIGLOSSECTOMY:

Invasive, well differentiated squamous cell carcinoma, 3.8 cm.

No perineural nor lymphovascular invasion identified.

Specimen margins are negative for tumor.

J. RIGHT NECK DISSECTION LEVEL 2-4 STITCH LEVEL 2B:

No malignancy seen in twenty lymph nodes (0/20).

K. RIGHT LEVEL 1B NECK DISSECTION:

ICD-O-3 NOS
Carcinoma, squamous cell
8070/3
Site Tongue NOS C02.9
7/23/13

[page 2 of 5]
No malignancy seen in salivary gland.

L. LEFT LEVEL 1A NECK DISSECTION:

No malignancy seen in two lymph nodes (0/2).

M. LEFT LEVEL 1 NECK DISSECTION:

No malignancy seen in salivary gland and five lymph nodes (0/5).

N. LEFT NECK DISSECTION LEVEL 2-4 STITCH AT LEVEL 2 B:

Metastatic carcinoma to one of twenty two lymph nodes (1/22).

Extranodal extension is NOT identified.

Metastatic deposit is 0.4 cm.

Surgical Pathology Cancer Case Summary:

LIP AND ORAL CAVITY: Incisional Biopsy, Excisional Biopsy, Resection

Specimen:
Hemiglossectomy

Received:
In formalin

Procedure:
Resection: Glossectomy
Neck (lymph node) dissection: Right and left level 1-4

Specimen Integrity:
Intact

Specimen Size:
Greatest dimensions: 6.0 x 3.0 x 3.0 cm

Specimen Laterality:
Left

Tumor Site:
Lateral border of tongue

Tumor Focality:
Single focus

Tumor Size:
Greatest dimension: 3.8 cm
Additional dimensions: 2.5 x 2.0 Cm

Histologic Type:
Squamous cell carcinoma, conventional

Histologic Grade:
G1: Well differentiated

Margins:
Uninvolved by invasive carcinoma

Lymph-Vascular Invasion:

[page 3 of 5]
Not identified

Perineural Invasion:
Not identified

Lymph Nodes, Extranodal Extension:
Not identified

Pathologic Staging (pTNM):
Primary Tumor (pT): pT2: Tumor more than 2 cm but not more than 4 cm in greatest dimension
Regional Lymph Nodes: pN1: Metastasis in a single ipsilateral lymph node, 3 cm or less in greatest dimension
Number of Lymph Nodes Examined: Right: 20 Left: 29
Number of Lymph Nodes Involved: 1 (Left)
Distant Metastasis: Not applicable

Electronically Signed Out By

Intraoperative Consultation:

- A. LEFT VENTRAL TONGUE MUCOSAL MARGIN - CLIP IS ANTERIOR, FS: Margins are negative for invasive carcinoma.
- B. LEFT ANTERIOR FLOOR OF MOUTH - CLIP ANTERIOR, FS: Margins are negative for invasive carcinoma.
- C. LEFT LINGUAL NERVE, FS: Margins are negative for invasive carcinoma.
- D. LEFT POSTERIOR FLOOR OF MOUTH MUCOSAL MARGIN CLIP - ANTERIOR, FS: Margins are negative for invasive carcinoma.
- E. LEFT DORSAL TONGUE MUCOSAL MARGIN - CLIP ANTERIOR, FS: This margin shows hyperkeratosis and mild atypia.
- F. DEEP MARGIN MID-TONGUE, FS: Margins are negative for invasive carcinoma.
- G. DEEP MARGIN POSTERIOR TONGUE, FS: Margins are negative for invasive carcinoma.
- H. DEEP MARGIN ANTERIOR TONGUE, FS: Margins are negative for invasive carcinoma.
- I. LEFT HEMIGLOSSECTOMY LONG STITCH ANTERIOR, SHORT STITCH DORSAL: Margins are negative for invasive carcinoma.

Clinical History:

Not provided

Operation Performed:

Left hemiglossectomy, bilateral neck dissection

Pre Operative Diagnosis:

Malignant neoplasm of tongue

Specimen(s) Received/Processing Information:

Fee Codes:

A: LEFT VENTRAL TONGUE MUCOSAL MARGIN - CLIP IS ANTERIOR, FS Frozen section x 1, FS Perm x 1	
B: LEFT ANTERIOR FLOOR OF MOUTH - CLIP ANTERIOR, FS Frozen section x 1, FS Perm x 1	
C: LEFT LINGUAL NERVE, FS Frozen section x 1, FS Perm x 1	
D: LEFT POSTERIOR FLOOR OF MOUTH MUCOSAL MARGIN CLIP - ANTERIOR, FS Frozen section x 1, FS Perm x 1	

[page 4 of 5]
E: LEFT DORSAL TONGUE MUCOSAL MARGIN - CLIP ANTERIOR, FS Frozen section x 1, FS Perm x 1 F: DEEP MARGIN MID-TONGUE, FS Frozen section x 1, FS Perm x 1 G: DEEP MARGIN POSTERIOR TONGUE, FS Frozen section x 1, FS Perm x 1 H: DEEP MARGIN ANTERIOR TONGUE, FS Frozen section x 1, FS Perm x 1 I: LEFT HEMIGLOSSECTOMY LONG STITCH ANTERIOR, SHORT STITCH DORSAL H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1 J: RIGHT NECK DISSECTION LEVEL 2-4 STITCH LEVEL 2B H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1 K: RIGHT LEVEL 1B NECK DISSECTION H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1 L: LEFT LEVEL 1A NECK DISSECTION H&E, Initial x 1, H&E, Initial x 1 M: LEFT LEVEL 1 NECK DISSECTION H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1 N: LEFT NECK DISSECTION LEVEL 2-4 STITCH AT LEVEL 2 B H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1	
--	--

Gross Description:

- A. Specimen is received fresh labeled "Left ventral tongue mucosal margin - clip is anterior, FS". The specimen consists of a 2.0 x 0.6 x 0.2 cm brown tissue fragment. Specimen is submitted in toto for frozen section (en face) in one cassette.
- B. Specimen is received fresh labeled "Left anterior floor of mouth - clip anterior, FS". The specimen consists of a 0.7 x 0.5 x 0.2 cm yellow-tan tissue fragment. Specimen is submitted in toto for frozen section in one cassette.
- C. Specimen is received fresh labeled "Left lingual nerve, FS". The specimen consists of a 0.5 x 0.3 x 0.2 cm tan tissue fragment. Specimen is submitted in toto for frozen section in one cassette.
- D. Specimen is received fresh labeled "Left posterior floor of mouth mucosal margin clip - anterior, FS". The specimen consists of two tan tissue fragments; the larger measuring 1.6 x 0.5 x 0.2 cm, the smaller measuring 0.6 x 0.3 x 0.2 cm. Specimen is submitted in toto for frozen section in one cassette.
- E. Specimen is received fresh labeled "Left dorsal tongue mucosal margin - clip anterior, FS". The specimen consists of two tan-brown tissue fragments; the larger measuring 3.5 x 0.4 x 0.2 cm, the smaller measuring 2.0 x 0.3 x 0.3 cm. Specimen is submitted in toto for frozen section (en face) in one cassette.
- F. Specimen is received fresh labeled "Deep margin mid-tongue, FS". The specimen consists of a 2.0 x 0.6 x 0.2 cm tan-brown tissue fragment. Specimen is submitted in toto for frozen section in one cassette.
- G. Specimen is received fresh labeled "Deep margin posterior tongue, FS". The specimen consists of a 1.6 x 0.6 x 0.3 cm brown tissue fragment. Specimen is submitted in toto (en face) for frozen section in one cassette.
- H. Specimen is received fresh labeled "Deep margin anterior tongue, FS". The specimen consists of a 1.5 x 0.5 x 0.3 cm brown tissue fragment. Specimen is submitted in toto (en face) for frozen section in one cassette.
- I. Specimen is received in formalin labeled "Left hemiglossectomy long stitch anterior, short stitch dorsal". The specimen consists of a left hemiglossectomy specimen measuring 6.0 x 3.0 x 3.0 cm. The medial margin is inked blue and the posterior margin is inked black. The mucosal surface is pink-tan and shows a 3.8 x 2.5 cm irregular ulcerated indurated white-tan ulcerated lesion. Cross sections through the ulcer 3.0 x 2.3 x 2.0 cm poorly defined lobulated white-tan firm tumoral lesion is deeply infiltrating the soft tissue (muscle). The tumor is grossly infiltrating the tongue mucosal surface, 0.2 cm from the medial (blue ink) margin, 1.0 cm from the posterior margin (inked black), 0.4 cm from the tip of the tongue and 0.3 cm from the inferior margin. Representative sections submitted in eight cassettes as follows:

Cassettes #1&2 The tumor in relation with the mucosal surface and medial margin

[page 5 of 5]
Cassettes #3&4 The tumor in relation with mucosal surface and posterior margin
Cassette #5 The tumor in relation with mucosal surface (tip of the tongue) and medial margin
Cassettes #6-8 The tumor in relation with inferior margin

- J. Specimen is received in formalin labeled "Right neck dissection level 2-4 stitch at level 2B". The specimen consists of a 13.0 x 4.0 x 1.3 cm yellow-tan tissue fragment. On cross sections twenty possible tan lymph nodes are identified; the largest measuring 2.5 x 1.0 x 0.6 cm located at the level 3. Received separately is a 1.3 x 1.0 x 0.6 cm additional irregular pink-tan soft tissue fragment. Cross section shows fibroadipose appearance.

Representative sections are submitted in ten cassettes as follows:

Cassette #1 Four possible lymph nodes from level 2
Cassette #2 Four possible lymph nodes from level 2
Cassette #3 Possible lymph node from level 2 (bisected)
Cassette #4 Possible lymph node from level 2 (serially sectioned)
Cassette #5 Possible lymph node from level 2 (serially sectioned)
Cassette #6 Possible lymph node from level 3 (serially sectioned)
Cassette #7 Three possible lymph nodes (the largest and the second largest bisected)
Cassette #8 Three possible lymph nodes (from level 4)
Cassettes #9&10 Possible lymph node from level 4 (bisected)

- K. Specimen is received in formalin labeled "Right level 1B neck dissection". The specimen consists of a 4.3 x 3.5 x 1.1 cm tan and lobulated soft tissue fragment (salivary gland). Cross sections show a tan lobulated unremarkable cut surface. Representative sections submitted in three cassettes.

- L. Specimen is received in formalin labeled "Left level 1A neck dissection". The specimen consists of two yellow-tan tissue fragments; the larger measuring 2.5 x 1.8 x 1.0 cm, the smaller measuring 1.0 x 0.5 x 0.3 cm. Cross sections show two possible lymph nodes, the larger measuring 0.6 x 0.5 x 0.5 cm.

Representative sections are submitted in two cassettes as follows:

Cassette #1 The larger possible lymph node (bisected)
Cassette #2 The smaller possible lymph node

- M. Specimen is received in formalin labeled "Left level 1 neck dissection". The specimen consists of a 4.5 x 3.5 x 1.8 cm tan lobulated soft tissue fragment (salivary gland). Attached to the external surface five possible lymph nodes are identified; the largest measuring 1.5 x 0.7 x 0.5 cm and the smaller measuring 0.3 cm. Cross section through the salivary gland shows tan lobulated unremarkable cut surface. Representative sections are submitted in five cassettes as follows:

Cassettes #1&2 Unremarkable salivary gland
Cassette #3 Three possible lymph nodes (largest bisected)
Cassette #4 Possible lymph node (bisected)
Cassette #5 Possible lymph node (bisected)

- N. Specimen is received in formalin labeled "Left neck dissection level 2-4 stitch at level 2B". The specimen consists of a 14.5 x 3.5 x 1.5 cm yellow-tan soft tissue fragment with fibroadipose tissue. On cross section twenty-two possible lymph nodes are grossly identified; the largest measuring 2.5 x 1.0 x 1.0 cm located at the level 2.

Representative sections are submitted in nine cassettes as follows:

Cassette #1 Four possible lymph nodes from level 2
Cassette #2 Three possible lymph nodes from level 2 (largest bisected)
Cassette #3 Possible lymph node from level 2 (bisected)
Cassette #4 Possible lymph node from level 2 (serially sectioned)
Cassette #5 Three possible lymph nodes from level 3 (largest bisected)
Cassette #6 Possible lymph node from level 3 (serially sectioned)
Cassette #7 Three possible lymph nodes from level 4 (largest bisected)
Cassette #8 Five possible lymph nodes from level 4
Cassette #9 Possible lymph node from level 4 (serially sectioned)

IHPAA Discrepancy		

Source: NCI Genomic Data Commons file d05e81db-27b6-4562-a640-c9fc4a28e63a (TCGA-IQ-A6SH.D0AD1DA4-7B1C-455C-8F80-8152CBAC726F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).